Gene-level copy-number profile of tumor specimen TCGA-WZ-A7V3-01A from TCGA case TCGA-WZ-A7V3, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 20.1 years (7,325 days).
Specimen TCGA-WZ-A7V3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.d2a9136a-513e-4059-a2cf-b26c0892e09b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WZ-A7V3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c0c28f5d-78a5-4e12-a00e-e6917dab05a8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,492; copy number 2: 18,367; copy number 3: 28,317; copy number 4: 7,032; copy number 5: 2,887; copy number 6: 218; copy number 7: 432; copy number 8: 814; copy number 9: 157; copy number 10: 91; copy number 12: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WZ-A7V3-01A-11D-A434-01): tumor purity 0.57, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,502 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:179,794,958–180,037,053, 1 gene, copy number 7 (within-gene range 5–7): PEX5L.
- chr3:179,875,376–195,990,318, 339 genes, copy number 7–8 (broad region; genes not listed).
- chr7:78,017,055–98,629,869, 256 genes, copy number 9–12 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 7–8 (broad region; genes not listed).
- chr20:31,257,664–32,439,319, 56 genes, copy number 7 (within-gene range 4–7): DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.

Autosomal genes at a single copy (total copy number 1): 1,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
